Somatic mutation profile of tumor specimen 2386c36d-8d5d-4fd4-bbfa-39cc8d (aliquot 2386c36d-8d5d-4fd4-bbfa-39cc8d_D6_1) from CPTAC case 14BR005, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.1 years (28,530 days).
Specimen 2386c36d-8d5d-4fd4-bbfa-39cc8d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba5eef45-2ab2-4c95-98c3-fdb917fcbcf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c28e911d-87c7-4998-b36a-f4cee1 (Blood Derived Normal), aliquot c28e911d-87c7-4998-b36a-f4cee1_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6dfacf7-994e-4e2b-a5f3-7466096886b9

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 4, 3'Flank 1, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP73 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1011406759; called by muse, mutect2
- CRTC2 | c.2015G>A p.S672N | Missense Mutation (SNP) | VAF 142/565 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs1300567039; called by muse, mutect2, varscan2
- CTSO | c.893A>G p.D298G | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1358576615; called by muse, mutect2, varscan2
- CYP8B1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 161/416 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs767458378, COSV60225655, COSV60226353; called by muse, mutect2, varscan2
- F9 | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940722, CM940723, CM980723; called by muse, mutect2, varscan2
- MUC16 | c.7366A>C p.T2456P | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV67479902; called by muse, mutect2, varscan2
- TBC1D31 | c.2603T>C p.I868T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs769771130; called by muse, mutect2, varscan2
- TDRD3 | c.842T>G p.M281R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52165142; called by muse, mutect2, varscan2
- WHAMM | c.1096C>A p.Q366K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as rs1173130833, COSV99724913; called by muse, mutect2, varscan2
- C10orf90 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ESRP2 | c.2032dup p.M678Nfs*25 (on ENST00000565858 / NM_001365264.1; = p.M668Nfs*25 on NM_024939.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 53/100 reads (53%) | called by mutect2, pindel, varscan2
- GRPEL2 | c.36_48delinsT p.V13_L16del | In Frame Del (DEL) | VAF 36/134 reads (27%) | called by pindel, varscan2*
- IQSEC3 | c.3214C>G p.P1072A | Missense Mutation (SNP) | VAF 138/278 reads (50%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- POGZ | c.3901G>A p.V1301M | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- PRR12 | c.2329C>A p.R777S (on ENST00000615927; = p.R1598S on NM_020719.3) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- SP3 | c.1225C>G p.Q409E | Missense Mutation (SNP) | VAF 103/293 reads (35%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZBTB2 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CCDC178 | c.1959C>T p.D653= (on ENST00000383096 / NM_001105528.3; = p.D615= on NM_198995.3) | Silent (SNP) | VAF 22/60 reads (37%) | called by mutect2, varscan2
- CCDC183 | c.1380G>A p.R460= | Silent (SNP) | VAF 95/255 reads (37%) | catalogued as rs1026849805; called by muse, mutect2, varscan2
- CLCN5 | c.732G>A p.S244= | Silent (SNP) | VAF 117/280 reads (42%) | catalogued as rs782320623; ClinVar: benign; called by muse, mutect2, varscan2
- LRRN3 | c.819T>C p.N273= | Silent (SNP) | VAF 84/177 reads (47%) | called by muse, mutect2, varscan2
- PRKDC | c.3447G>A p.K1149= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as COSV58057233; called by muse, mutect2, varscan2
- PTPRE | c.1791G>A p.E597= | Silent (SNP) | VAF 96/215 reads (45%) | catalogued as COSV99617536; called by muse, mutect2, varscan2
- AKAP9 | c.930+16G>C | Intron (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501570 del T | 5'Flank (DEL) | VAF 13/116 reads (11%) | called by mutect2, pindel, varscan2
- ATP8B3 | c.1552+269G>T | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- FANCA | c.2778+64T>A | Intron (SNP) | VAF 146/241 reads (61%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46833065 C>G | 3'Flank (SNP) | VAF 117/306 reads (38%) | catalogued as rs756797299; called by muse, mutect2, varscan2
- PLEKHG5 | c.-54+311C>T | Intron (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
